Gene-level copy-number profile of tumor specimen ALCH-B1JW-TTP1-A from ALCHEMIST case ALCH-B1JW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.1 years (25,986 days).
Specimen ALCH-B1JW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94fcf3e6-0752-4383-aed5-fbaf4b63518a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1JW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/8cc70d78-94c4-4ce3-a2fc-cd99ca3b7962

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 10,649; copy number 2: 44,759; copy number 3: 2,301; copy number 4: 106; copy number 5: 357; copy number 6: 77; copy number 7: 4; copy number 8: 90; copy number 12: 10; copy number 14: 7; copy number 17: 23.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,279,125–13,285,174, 2 genes: RNU6-771P, PRAMEF8.
- chr4:8,959,628–8,963,981, 1 gene: UNC93B8.
- chr5:175,703,898–175,704,004, 1 gene: RNU6-226P.
- chr10:42,871,521–42,874,060, 1 gene: LINC02623.
- chr13:111,316,184–111,901,264, 4 genes (within-gene range 0–1): TEX29, AL359649.1, LINC02337, LINC00354.
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–20): CICP25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 568 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:37,899,363–40,269,719, 35 genes, copy number 7–17: LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P.
- chr5:44,300,247–44,389,706, 1 gene, copy number 8 (within-gene range 3–8): FGF10.
- chr8:2,493,876–2,838,823, 7 genes, copy number 14: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:37,067,441–46,793,064, 178 genes, copy number 5–8 (broad region; genes not listed).
- chr8:126,474,189–144,444,440, 303 genes, copy number 5–7 (broad region; genes not listed).
- chr14:36,516,392–37,596,059, 20 genes, copy number 6–8 (within-gene range 1–12): NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr18:61,905,255–63,320,128, 20 genes, copy number 8 (within-gene range 3–8): PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2.
- chr19:1,086,574–1,095,380, 1 gene, copy number 5 (within-gene range 2–5): POLR2E.
- chr19:1,275,530–1,279,244, 1 gene, copy number 5: FAM174C.
- chr20:62,136,733–62,143,440, 1 gene, copy number 8: PSMA7.
- chr20:62,214,960–62,220,278, 1 gene, copy number 6: HRH3.

Autosomal genes at a single copy (total copy number 1): 8,328. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
